FM case AD14130 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/9b157d52-92d7-4622-99fa-bc7445ecd10d

Male, 75.9 years: Duct adenocarcinoma, NOS (ICD-O-3 8500/3) of the prostate gland; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
